Somatic mutation profile of tumor specimen PCProject_0639_T1_WES (aliquot PCProject_0639_T1_WES_1) from CMI case PCProject_0639, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 54.0 years (19,724 days).
Specimen PCProject_0639_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6864adb8-6e02-4c2a-91c5-a81a7e880b4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0639_BLOOD_BC (Blood Derived Normal), aliquot PCProject_0639_BLOOD_BC_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9acf8c10-9ba2-443d-ad99-b27447717e23

The open-access MAF lists 49 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, Frame Shift Del 5, Intron 4, 5'UTR 3, Nonsense Mutation 2, 3'UTR 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEST3 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV58306174; called by muse, mutect2, varscan2
- COL8A2 | c.1258C>A p.P420T | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs772297339; called by muse, mutect2, varscan2
- DSC1 | c.1328C>G p.S443C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.739); catalogued as rs1331894749, COSV57149838; called by muse, mutect2, varscan2
- FAM199X | c.337C>G p.P113A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.348); catalogued as COSV101534168, COSV72419869; called by muse, mutect2, varscan2
- MYOD1 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51453578; called by muse, mutect2, varscan2
- POTEG | c.1077C>A p.D359E | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.997); catalogued as COSV101192796; called by muse, mutect2
- S1PR4 | c.341C>G p.A114G | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV55739970; called by muse, mutect2, varscan2
- SLC28A1 | c.1004T>A p.L335H | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.275); catalogued as rs1474180045; called by muse, mutect2, varscan2
- SLC2A5 | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368307795; called by muse, mutect2, varscan2
- STAG2 | c.2139C>A p.Y713* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV54366695; called by muse, mutect2, varscan2
- TF | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99396575; called by muse, mutect2
- WDTC1 | c.1949G>A p.R650Q (on ENST00000319394 / NM_001276252.2; = p.R649Q on NM_015023.5) | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs1477182799; called by muse, mutect2, varscan2
- WIF1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs774356039, COSV54130296; called by muse, mutect2, varscan2
- ANKRD30A | c.1172C>A p.T391K (on ENST00000611781; = p.T335K on NM_052997.2) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.403); called by mutect2, varscan2
- AP3B1 | c.1547A>G p.D516G | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP22 | c.28A>G p.R10G | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BEST3 | c.1584_1590del p.S529Lfs*57 | Frame Shift Del (DEL) | VAF 18/186 reads (10%) | called by mutect2, pindel
- CACNA1S | c.4847del p.N1616Tfs*18 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- CD83 | c.468_487del p.T157* | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel
- CHN1 | c.695A>G p.Q232R | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- DCT | c.1191_1206del p.F398Lfs*5 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel
- DGLUCY | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- GOLGB1 | c.9246C>G p.H3082Q | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNG3 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL33 | c.683C>A p.P228Q | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- KPNA6 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.146); called by muse, mutect2
- OR6T1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PTEN | c.543_547delinsAT p.L182_K183delins* | Nonsense Mutation (DEL) | VAF 9/73 reads (12%) | called by pindel, varscan2*
- QTRT1 | c.531-7G>T | Splice Region (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- SDK1 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIM1 | c.1014del p.L340Cfs*25 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by pindel, varscan2
- TOP2B | c.3109C>G p.Q1037E (on ENST00000264331 / NM_001330700.2; = p.Q1032E on NM_001068.3) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2
- DMD | c.8430G>C p.L2810= | Silent (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- FAT1 | c.4398T>C p.P1466= | Silent (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- GRIN2C | c.3420C>T p.A1140= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs1228487932; called by muse, mutect2, varscan2
- MPEG1 | c.1698C>A p.A566= | Silent (SNP) | VAF 24/173 reads (14%) | called by mutect2, varscan2
- NPAS1 | c.999G>C p.L333= | Silent (SNP) | VAF 24/224 reads (11%) | catalogued as rs1159911546; called by muse, mutect2
- NPAS4 | c.892T>C p.L298= | Silent (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- OR5T3 | c.531C>T p.S177= | Silent (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- ATP5F1C | c.-5C>G | 5'UTR (SNP) | VAF 24/148 reads (16%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2918C>T | 3'UTR (SNP) | VAF 11/100 reads (11%) | catalogued as rs1005199620; called by muse, mutect2, varscan2
- GRK2 | c.*1033C>T | 3'UTR (SNP) | VAF 8/55 reads (15%) | catalogued as rs1437009782; called by muse, mutect2, varscan2
- KLK2 | c.-9T>G | 5'UTR (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2, varscan2
- PDE3A | c.1011+15442G>C | Intron (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- PGC | c.648-474T>C | Intron (SNP) | VAF 10/155 reads (6%) | called by muse, mutect2
- POLR3E | c.1944+9A>G | Intron (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.10360+5173C>G | Intron (SNP) | VAF 5/29 reads (17%) | called by mutect2, varscan2
- TTPA | c.-2G>A | 5'UTR (SNP) | VAF 38/190 reads (20%) | called by muse, mutect2, varscan2
- USP27X | chrX:49878666 G>C | 5'Flank (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2
